Somatic mutation profile of tumor specimen TCGA-G3-A25W-01A (aliquot TCGA-G3-A25W-01A-11D-A16V-10) from TCGA case TCGA-G3-A25W, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 79.4 years (29,018 days).
Specimen TCGA-G3-A25W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6021fde-f05f-4384-a3fe-e818e282f8f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A25W-11A (Solid Tissue Normal), aliquot TCGA-G3-A25W-11A-12D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45135f2b-68a4-4428-8336-ea8aa4acd36e

The open-access MAF lists 89 somatic variants for this specimen: 66 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 16, Nonsense Mutation 4, Frame Shift Del 4, Intron 3, 3'UTR 2, Splice Site 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDOB | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV66397457; called by muse, mutect2, varscan2
- C11orf96 | c.1171A>G p.K391E (on ENST00000339446; = p.K78E on NM_001145033.2) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as COSV59708073; called by muse, mutect2, varscan2
- C4orf51 | c.367-1G>T p.X123_splice | Splice Site (SNP) | VAF 20/175 reads (11%) | catalogued as COSV71263846; called by muse, varscan2
- C4orf51 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV71263850; called by muse, varscan2
- CKS1B | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 48/160 reads (30%) | catalogued as COSV58315771; called by muse, mutect2, varscan2
- COPS4 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV52313921; called by muse, mutect2
- DCHS1 | c.2456G>T p.G819V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55031759; called by muse, mutect2
- ELFN1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1428412093, COSV70033877; called by muse, mutect2, varscan2
- FIG4 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368625871; ClinVar: uncertain significance; called by muse, varscan2
- FLRT3 | c.1678T>A p.S560T | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.083); catalogued as COSV53954351; called by muse, mutect2, varscan2
- FNBP4 | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV55446841; called by muse, mutect2, varscan2
- GALC | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV54323724; called by muse, mutect2, varscan2
- GON7 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as rs1481000687, COSV99184148; called by muse, mutect2
- GRXCR2 | c.450G>C p.E150D | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV65060773; called by muse, mutect2, varscan2
- HAUS3 | c.372A>C p.Q124H | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54722003; called by muse, mutect2, varscan2
- HERC4 | c.1894A>G p.I632V | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53268949; called by muse, mutect2, varscan2
- HESX1 | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV55843031; called by muse, mutect2, varscan2
- IFI16 | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV55531712; called by muse, mutect2, varscan2
- IRAG2 | c.2943T>A p.Y981* (on ENST00000636465; = p.Y26* on NM_006152.4 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | catalogued as COSV63137823, COSV63139280; called by muse, mutect2, varscan2
- KLK1 | c.353G>C p.S118T | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56826150; called by muse, mutect2, varscan2
- MAPKAPK5 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761251796, COSV73411026; called by muse, mutect2, varscan2
- MARCO | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as rs1222641496, COSV59052476; called by muse, mutect2, varscan2
- METTL2B | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776752874, COSV52308025; called by muse, mutect2, varscan2
- MLPH | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV52818602; called by muse, mutect2, varscan2
- MYO16 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV51780987; called by muse, varscan2
- MYO3B | c.3294G>T p.W1098C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV58696539; called by muse, mutect2, varscan2
- NELFB | c.1632-1G>A p.X544_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV58025444; called by muse, mutect2, varscan2
- NEMF | c.1883A>G p.E628G | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53589717; called by muse, mutect2, varscan2
- NPAT | c.3665C>T p.S1222L | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs760913450, COSV53716504; called by muse, mutect2, varscan2
- OSBPL8 | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV53879223; called by muse, mutect2, varscan2
- OTOGL | c.1921C>A p.Q641K (on ENST00000547103; = p.Q632K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV72005913; called by mutect2, varscan2
- PASD1 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as rs769677472, COSV64854370; called by muse, mutect2, varscan2
- PCDHGA8 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV53910547; called by mutect2, varscan2
- PDE10A | c.2183G>T p.G728V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781103938, COSV63092315, COSV63100681; called by muse, mutect2, varscan2
- PHKB | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54516145; called by muse, varscan2
- PPP1R15A | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs767917201, COSV52338441; called by mutect2, varscan2
- PRPS2 | c.851G>C p.C284S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.407); catalogued as COSV66179297; called by muse, mutect2, varscan2
- RAB34 | c.626T>C p.F209S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56385501; called by muse, mutect2, varscan2
- RAPGEF6 | c.987T>A p.S329R | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.199); catalogued as COSV57241498; called by muse, mutect2, varscan2
- RASAL2 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV62710732; called by muse, mutect2, varscan2
- RESF1 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs756631544, COSV57020159; called by muse, mutect2, varscan2
- RIN1 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60925680; called by muse, mutect2
- RNF123 | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59684789; called by muse, varscan2
- SEC23A | c.1632G>T p.R544S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV56971672; called by muse, mutect2, varscan2
- SERPINA10 | c.1016A>G p.K339R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.625); catalogued as COSV56227605; called by muse, mutect2, varscan2
- SHCBP1 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57646599; called by muse, mutect2, varscan2
- SPG11 | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV55991769; called by muse, mutect2, varscan2
- SSC5D | c.3877C>T p.P1293S | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV101046733; called by muse, mutect2, varscan2
- ST8SIA1 | c.213C>G p.N71K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as COSV53951500; called by muse, mutect2, varscan2
- THSD7B | c.1864T>C p.S622P | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV55661906; called by muse, mutect2, varscan2
- TMEM232 | c.1005C>A p.S335R | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV70266309; called by muse, mutect2, varscan2
- TRAIP | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs567150349, COSV58913235; called by muse, mutect2, varscan2
- TRAM1 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV51596984; called by muse, mutect2, varscan2
- TTN | c.92134G>A p.V30712I (on ENST00000591111; = p.V23288I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | PolyPhen benign (0.003); catalogued as rs1250490166, COSV59919891; called by muse, mutect2, varscan2
- UBASH3B | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.3); catalogued as COSV52491352; called by muse, varscan2
- UTRN | c.2980C>T p.Q994* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as COSV62329669; called by muse, mutect2, varscan2
- VWA3A | c.1952A>G p.E651G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as COSV55388586; called by muse, mutect2, varscan2
- WDR7 | c.1182A>G p.I394M | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV54349249; called by muse, mutect2, varscan2
- ZAN | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.259); catalogued as COSV61806049; called by muse, mutect2, varscan2
- ZCCHC14 | c.1240G>A p.G414S (on ENST00000268616; = p.G551S on NM_015144.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.091); catalogued as COSV51884509; called by muse, varscan2
- ZNF75D | c.501A>C p.Q167H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV66132455; called by muse, mutect2, varscan2
- BEST1 | c.433_435del p.T145del | In Frame Del (DEL) | VAF 10/30 reads (33%) | called by pindel, varscan2
- GSE1 | c.1026_1038del p.E342Dfs*87 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- HEATR5A | c.2380del p.V794Lfs*22 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- REV1 | c.3395_3396del p.S1132Cfs*11 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by pindel, varscan2
- RLIM | c.622del p.Q208Rfs*28 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | called by mutect2, pindel, varscan2
- BTBD9 | c.1320C>T p.V440= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV58421677, COSV58433936; called by muse, mutect2, varscan2
- CNPPD1 | c.1173A>G p.Q391= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs779568915, COSV55405829; called by muse, mutect2, varscan2
- DAB2 | c.2169C>A p.S723= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100298005, COSV57912825; called by muse, mutect2, varscan2
- EYS | c.5223T>C p.D1741= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs1308362084, COSV58195725; called by muse, mutect2, varscan2
- FAM171A1 | c.1840C>T p.L614= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV65314004; called by muse, mutect2, varscan2
- FSCN1 | c.1398C>T p.G466= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs568861608, COSV61016959; called by muse, mutect2, varscan2
- GPS1 | c.225G>A p.L75= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV57647865; called by muse, mutect2, varscan2
- GUCD1 | c.690T>C p.D230= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, varscan2
- HJV | c.30C>T p.P10= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs782076129, COSV60951403; called by muse, mutect2, varscan2
- KDM5B | c.2769G>A p.V923= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV52505141, COSV52515096; called by muse, mutect2, varscan2
- LRRC7 | c.2061C>T p.T687= (on ENST00000651989 / NM_001370785.2; = p.T654= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV50418705; called by muse, varscan2
- NBR1 | c.1746T>G p.P582= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV57831138; called by muse, mutect2
- PCSK4 | c.1158G>A p.A386= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1002821734, COSV56298507; called by muse, varscan2
- POLK | c.2190T>C p.S730= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV54032848; called by muse, mutect2, varscan2
- RTTN | c.348T>C p.P116= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV55342149; called by muse, mutect2, varscan2
- TNRC6A | c.2406G>A p.G802= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs113829020, COSV59361978; called by muse, mutect2, varscan2
- CPLANE1 | c.*616A>G | 3'UTR (SNP) | VAF 21/120 reads (18%) | catalogued as rs186540080; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRG1BP | n.646C>A | RNA (SNP) | VAF 15/244 reads (6%) | called by muse, mutect2
- LRPPRC | c.1582+1339A>T | Intron (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- RPGR | c.2520+1524T>G | Intron (SNP) | VAF 36/161 reads (22%) | catalogued as COSV58833033; called by muse, mutect2, varscan2
- TMEM99 | n.1176A>G | RNA (SNP) | VAF 18/58 reads (31%) | catalogued as rs1375106384, COSV100053980; called by muse, mutect2, varscan2
- UQCRH | c.*29C>T | 3'UTR (SNP) | VAF 25/153 reads (16%) | catalogued as COSV100295514; called by muse, mutect2, varscan2
- XRRA1 | c.280-25G>A | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
